Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A44Q, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A44Q-06A (Metastatic).

Procurement Date: Laterality: Lymph node architectures are replaced by tumor cells. Tumor is composed of spindle or oval tumor cells with quite scant cytoplasm. Tumor cells have a quite low nucleo-cytoplasmic ratio. Nucleus varies in shape and size with large esinophilic nucleoli. Mitotic figures are common.

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Surgical resection

Tumor site: Lymph node, inguinal

Tumor size: 5 x 3 x 2 cm

Tumor features: None specified

Satellite nodules: Not specified

Histologic type: Metastatic neoplasm, malignant melanoma

Histologic grade: Poorly differentiated

Lymph nodes: 4/7 positive for metastasis (Left inguinal and pelvic lymph node 4/7)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
melanoma, NOS
8720/3
Site: lymph node, inguinal
8131/12
RD
C77.4

Source: NCI Genomic Data Commons file 85d6e91b-ffdb-480d-9dd8-b61167286cb7 (TCGA-EB-A44Q.AC3C89E0-DE03-45B9-8360-1207D39A261B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).